Somatic mutation profile of tumor specimen TCGA-IN-A6RR-01A (aliquot TCGA-IN-A6RR-01A-12D-A32N-08) from TCGA case TCGA-IN-A6RR, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; Tumor grade: G3; Age at diagnosis: 84.1 years (30,734 days).
Specimen TCGA-IN-A6RR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef4297a9-dff0-4559-a091-d6d7e174c5f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IN-A6RR-10A (Blood Derived Normal), aliquot TCGA-IN-A6RR-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d855dd43-a5d5-4f16-a2aa-1dba095f3b69

The open-access MAF lists 156 somatic variants for this specimen: 111 protein-altering or splice-affecting, 42 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 42, Nonsense Mutation 8, Splice Site 3, Frame Shift Ins 2, 3'Flank 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.3404G>A p.R1135Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758997, COSV60787834; called by muse, mutect2, varscan2
- TP53 | c.448_460del p.T150Afs*16 | Frame Shift Del (DEL) | VAF 52/78 reads (67%) | catalogued as rs1064792930, COSV52702198; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- A1BG | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 90/216 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.134); catalogued as COSV99568748; called by muse, mutect2, varscan2
- ACKR2 | c.646C>A p.L216I | Missense Mutation (SNP) | VAF 81/223 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV99825807, COSV99825831; called by muse, mutect2, varscan2
- ADGRE5 | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 65/206 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99663390; called by muse, mutect2, varscan2
- ADNP | c.3013G>T p.D1005Y | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100823885; called by muse, mutect2, varscan2
- AHNAK2 | c.8275G>T p.D2759Y | Missense Mutation (SNP) | VAF 93/276 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100319174; called by muse, mutect2, varscan2
- AOX1 | c.589-1G>A p.X197_splice | Splice Site (SNP) | VAF 33/112 reads (29%) | catalogued as COSV101022182; called by muse, mutect2, varscan2
- ARHGAP20 | c.601T>G p.F201V | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.517); catalogued as COSV99505587; called by muse, mutect2, varscan2
- AXIN1 | c.1692G>A p.W564* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV51986389; called by muse, mutect2, varscan2
- C7orf33 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs1313601253, COSV100188955; called by muse, mutect2, varscan2
- C8orf34 | c.1112T>C p.L371P | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57404832; called by muse, mutect2, varscan2
- CABYR | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1176830004, COSV100510216; called by muse, mutect2
- CCDC173 | c.484A>C p.S162R | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV101352371; called by muse, mutect2, varscan2
- CCDC178 | c.229T>G p.F77V | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100287139; called by muse, mutect2, varscan2
- CD1C | c.474G>T p.L158F | Missense Mutation (SNP) | VAF 139/363 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV100939472, COSV63807331; called by muse, mutect2, varscan2
- CDH12 | c.1877T>A p.I626K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101203413; called by muse, mutect2, varscan2
- CDH12 | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 102/123 reads (83%) | catalogued as rs1186005652, COSV101203414; called by muse, mutect2, varscan2
- CDH12 | c.868A>G p.R290G | Missense Mutation (SNP) | VAF 110/141 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV101203415; called by muse, mutect2, varscan2
- CELSR2 | c.3034C>T p.R1012C | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as rs372546163; called by muse, mutect2, varscan2
- CHAF1A | c.2023G>A p.G675R | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100011530; called by muse, mutect2, varscan2
- CNTLN | c.1439A>C p.E480A | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99265962; called by muse, mutect2
- CPAMD8 | c.3784G>C p.V1262L (on ENST00000651564; = p.V1215L on NM_015692.5) | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101488622; called by muse, mutect2, varscan2
- CREBBP | c.3506G>A p.R1169H | Missense Mutation (SNP) | VAF 50/74 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52118129; called by muse, mutect2, varscan2
- CSKMT | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV100649311; called by muse, mutect2, varscan2
- DEDD | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.761); catalogued as COSV100919098; called by muse, mutect2, varscan2
- DNAI2 | c.1621C>G p.L541V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100210163; called by muse, mutect2, varscan2
- DOCK4 | c.5234G>A p.G1745E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV101448014; called by muse, varscan2
- DSCAML1 | c.4908T>G p.I1636M (on ENST00000321322; = p.I1576M on NM_020693.4) | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV100357419; called by muse, mutect2, varscan2
- DYNC2H1 | c.11284T>G p.L3762V | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV100519933; called by muse, mutect2, varscan2
- EMILIN2 | c.464G>T p.R155M | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as COSV99598997; called by muse, mutect2, varscan2
- EPHA3 | c.199A>G p.T67A | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100349362; called by muse, mutect2, varscan2
- EPHB1 | c.1321C>T p.H441Y | Missense Mutation (SNP) | VAF 94/244 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV101214656; called by muse, mutect2, varscan2
- ETV4 | c.1289T>C p.L430S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99292690; called by muse, mutect2
- FANCM | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.254); catalogued as rs886050502, COSV57506727; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT2 | c.11929C>T p.Q3977* | Nonsense Mutation (SNP) | VAF 34/122 reads (28%) | catalogued as rs757978010, COSV99944310; called by muse, mutect2, varscan2
- FAT2 | c.6209T>A p.F2070Y | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV99944311; called by muse, mutect2, varscan2
- FIGN | c.221A>C p.K74T | Missense Mutation (SNP) | VAF 86/277 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60767113; called by muse, mutect2, varscan2
- FITM2 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 37/82 reads (45%) | catalogued as COSV67679016; called by muse, mutect2, varscan2
- FLNB | c.4061+2T>C p.X1354_splice | Splice Site (SNP) | VAF 12/150 reads (8%) | catalogued as COSV99915264; called by muse, mutect2
- FLRT2 | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.483); catalogued as COSV100421142, COSV58140483; called by muse, mutect2, varscan2
- GABRA1 | c.1104C>A p.Y368* | Nonsense Mutation (SNP) | VAF 42/138 reads (30%) | catalogued as COSV50099123, COSV99196334; called by muse, mutect2, varscan2
- GRM1 | c.2639A>C p.K880T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.494); catalogued as COSV51140791, COSV99269463; called by muse, mutect2, varscan2
- HCAR1 | c.671T>C p.V224A | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.052); catalogued as COSV100811844; called by muse, mutect2, varscan2
- HERC6 | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.958); catalogued as rs767435596, COSV52033223; called by muse, mutect2, varscan2
- HMGCLL1 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.784); catalogued as rs1433675878, COSV51443884; called by muse, mutect2, varscan2
- IBSP | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 61/92 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as rs758115196, COSV56894829; called by muse, mutect2, varscan2
- IKZF1 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1270036178, COSV58785900; called by muse, mutect2, varscan2
- IPO8 | c.2993C>T p.A998V | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV99805704; called by muse, mutect2, varscan2
- IRAG1 | c.2678C>G p.A893G | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.756); catalogued as COSV101351798; called by muse, mutect2, varscan2
- KCNJ12 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145471133; called by muse, varscan2
- KCNN2 | c.292G>A p.G98R (on ENST00000264773; = p.G310R on NM_021614.4) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.483); catalogued as rs778815500, COSV99300876; called by muse, mutect2, varscan2
- KMT2D | c.10501G>A p.V3501M | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99986360; called by muse, mutect2, varscan2
- L3MBTL4 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV99531556; called by muse, mutect2, varscan2
- LAMB2 | c.3350G>A p.R1117H | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs139821983, COSV100026565; called by muse, mutect2, varscan2
- LRRTM1 | c.245C>A p.A82D | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99703334; called by muse, mutect2, varscan2
- LRRTM4 | c.231A>C p.K77N | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.841); catalogued as COSV101297753; called by muse, mutect2, varscan2
- MAGEL2 | c.3127C>T p.R1043C | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as rs772582222, COSV100046270; called by muse, mutect2, varscan2
- MC3R | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 94/225 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1481948431, COSV54763393; called by muse, mutect2, varscan2
- MFSD2B | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs534559168, COSV100601264; called by muse, mutect2, varscan2
- MRTFB | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100371750; called by muse, mutect2, varscan2
- MSANTD3 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV100614413; called by muse, mutect2, varscan2
- MYO15A | c.9571C>A p.R3191S | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99233632, COSV99234697; called by muse, mutect2, varscan2
- NIN | c.3211C>T p.Q1071* | Nonsense Mutation (SNP) | VAF 187/364 reads (51%) | catalogued as COSV55403141, COSV99815596; called by muse, mutect2, varscan2
- NT5C1A | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs557786217, COSV52494161; called by muse, mutect2, varscan2
- OR10K1 | c.316T>G p.F106V | Missense Mutation (SNP) | VAF 84/236 reads (36%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.996); catalogued as COSV99194023; called by muse, mutect2, varscan2
- OR10K2 | c.848C>A p.P283Q | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100149689, COSV59222052; called by muse, mutect2, varscan2
- OR2L8 | c.220T>C p.S74P | Missense Mutation (SNP) | VAF 137/407 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100594347; called by muse, mutect2, varscan2
- OR4K14 | c.56C>A p.T19N | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100520543; called by muse, mutect2, varscan2
- OR4P4 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 24/111 reads (22%) | catalogued as COSV100111882; called by muse, mutect2, varscan2
- OR8J3 | c.181T>G p.F61V | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100041072, COSV56879215, COSV56883780; called by muse, mutect2, varscan2
- PCDHGA4 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); catalogued as rs746094461, COSV53925110; called by muse, mutect2, varscan2
- PDE3B | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as COSV99963409; called by muse, mutect2
- PDE7B | c.1203C>A p.N401K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.099); catalogued as COSV100368405; called by muse, mutect2, varscan2
- PDZD3 | c.1586G>T p.R529M (on ENST00000531114; = p.R449M on NM_024791.4) | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); catalogued as COSV100501625; called by muse, mutect2, varscan2
- PDZK1IP1 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs150391778; called by muse, mutect2, varscan2
- PHLPP2 | c.3510C>G p.D1170E | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100673862; called by muse, mutect2
- POU3F2 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV100099413, COSV100099524, COSV60409436; called by muse, mutect2, varscan2
- PTH1R | c.650G>A p.C217Y | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100481203; called by muse, mutect2, varscan2
- RASSF9 | c.935G>C p.S312T | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100771576, COSV100771624, COSV63432979; called by muse, mutect2
- REG1B | c.340A>C p.S114R | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100521542; called by muse, mutect2, varscan2
- RPRD1B | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); catalogued as COSV100987343; called by muse, mutect2, varscan2
- SFMBT1 | c.2219C>T p.S740F | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as COSV99966492; called by mutect2, varscan2
- SLC38A4 | c.653A>G p.N218S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.103); catalogued as COSV99873222; called by muse, mutect2, varscan2
- SLCO4C1 | c.1394T>G p.L465R | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100196199, COSV60512282; called by muse, mutect2, varscan2
- SYNE3 | c.2192G>A p.R731K | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100516613; called by muse, mutect2, varscan2
- SYT4 | c.1201G>T p.G401C | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as COSV99674527; called by muse, mutect2, varscan2
- SYT8 | c.1093C>A p.H365N | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99425647; called by muse, mutect2, varscan2
- TG | c.6280C>A p.Q2094K | Missense Mutation (SNP) | VAF 263/621 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as COSV55063990, COSV99603675; called by muse, mutect2, varscan2
- TGIF2LY | c.455C>A p.T152K | Missense Mutation (SNP) | VAF 42/57 reads (74%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100339715; called by muse, mutect2, varscan2
- TNFRSF25 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs567034403, COSV61068564; called by muse, mutect2, varscan2
- TNN | c.1011A>C p.E337D | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV53428977; called by muse, mutect2, varscan2
- TP63 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53217852; called by muse, mutect2, varscan2
- TTN | c.78037G>A p.V26013I (on ENST00000591111; = p.V18589I on NM_003319.4) | Missense Mutation (SNP) | VAF 177/347 reads (51%) | PolyPhen benign (0.009); catalogued as rs1027584774, COSV100633521; called by muse, mutect2, varscan2
- TTN | c.10841A>G p.K3614R (on ENST00000591111; = p.K3568R on NM_003319.4) | Missense Mutation (SNP) | VAF 182/342 reads (53%) | catalogued as COSV100633523; called by muse, mutect2, varscan2
- TUFM | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV100493239, COSV100493242; called by muse, mutect2, varscan2
- USH2A | c.14522C>T p.A4841V | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as rs1317945547, COSV100243547; called by muse, mutect2, varscan2
- USP39 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100084146; called by muse, mutect2, varscan2
- VWA5A | c.1910C>A p.P637H | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100827980; called by muse, mutect2, varscan2
- WDFY3 | c.7837G>A p.D2613N | Missense Mutation (SNP) | VAF 130/278 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV55697355, COSV99886022; called by muse, mutect2, varscan2
- WDR19 | c.3281G>A p.R1094H | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs781620821, COSV99976018; called by muse, mutect2, varscan2
- WIPF3 | c.1351A>C p.S451R | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV99635325; called by muse, mutect2, varscan2
- ZNF135 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs371178818; called by muse, mutect2, varscan2
- ZNF208 | c.578G>C p.R193T | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.279); catalogued as COSV68101588, COSV68107479; called by muse, mutect2, varscan2
- ZNF442 | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.734); catalogued as COSV99664538; called by muse, mutect2, varscan2
- ZNF676 | c.491A>C p.K164T (on ENST00000650058; = p.K132T on NM_001001411.3) | Missense Mutation (SNP) | VAF 78/151 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV68092763; called by muse, mutect2, varscan2
- ZNF780B | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 66/89 reads (74%) | catalogued as COSV99666222; called by muse, mutect2, varscan2
- IGF2R | c.5833+2_5833+3del p.X1945_splice | Splice Site (DEL) | VAF 24/90 reads (27%) | called by pindel, varscan2
- MBD6 | c.1067_1068insT p.S357Lfs*29 | Frame Shift Ins (INS) | VAF 55/105 reads (52%) | called by mutect2, pindel*, varscan2*
- PLEKHA6 | c.2471dup p.I825Dfs*2 | Frame Shift Ins (INS) | VAF 11/26 reads (42%) | called by mutect2, varscan2
- PRAMEF18 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 109/540 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- ABCA7 | c.2034G>A p.R678= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV99566763; called by muse, mutect2, varscan2
- ADIPOR2 | c.711T>C p.Y237= | Silent (SNP) | VAF 62/165 reads (38%) | catalogued as COSV100840232; called by muse, mutect2, varscan2
- ARHGAP30 | c.900T>C p.H300= | Silent (SNP) | VAF 172/378 reads (46%) | catalogued as rs543156923, COSV100920549; called by muse, mutect2, varscan2
- ARMC4 | c.1422T>C p.C474= | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as COSV100537484; called by muse, mutect2, varscan2
- ATP10A | c.3774G>A p.P1258= | Silent (SNP) | VAF 64/209 reads (31%) | catalogued as rs768985513, COSV63515862; called by muse, mutect2, varscan2
- C1QL4 | c.342G>A p.A114= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV99226633, COSV99227077; called by muse, mutect2, varscan2
- CCT7 | c.1152G>A p.E384= | Silent (SNP) | VAF 55/167 reads (33%) | catalogued as COSV99241265; called by muse, mutect2, varscan2
- CD47 | c.246T>C p.S82= | Silent (SNP) | VAF 71/163 reads (44%) | catalogued as COSV100790174; called by muse, mutect2, varscan2
- EXD3 | c.1914G>T p.L638= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs368003193; called by muse, mutect2, varscan2
- FGD4 | c.1377C>T p.S459= | Silent (SNP) | VAF 13/187 reads (7%) | catalogued as rs1263595719, COSV99847698; called by muse, mutect2
- FLG2 | c.6C>T p.T2= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as rs1390172532, COSV101166280, COSV66170253; called by muse, mutect2, varscan2
- FNDC3A | c.2925T>G p.T975= (on ENST00000492622 / NM_001079673.2; = p.T919= on NM_014923.5) | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV101257008; called by muse, mutect2, varscan2
- FUT1 | c.702T>C p.G234= | Silent (SNP) | VAF 86/238 reads (36%) | catalogued as COSV100038292; called by muse, mutect2, varscan2
- HIVEP3 | c.2043A>G p.T681= | Silent (SNP) | VAF 64/158 reads (41%) | catalogued as COSV99914210; called by muse, mutect2, varscan2
- HYDIN | c.9939C>T p.A3313= | Silent (SNP) | VAF 61/89 reads (69%) | catalogued as rs553587582, COSV66863115; called by muse, mutect2, varscan2
- KCNQ3 | c.1239A>G p.K413= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as COSV101196533; called by muse, mutect2, varscan2
- KIF1A | c.1263C>T p.H421= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as rs369856336, COSV100242560; called by muse, mutect2, varscan2
- L3MBTL1 | c.2151G>A p.K717= (on ENST00000418998 / NM_001377303.1; = p.K627= on NM_015478.7) | Silent (SNP) | VAF 54/181 reads (30%) | catalogued as COSV100917070; called by muse, mutect2, varscan2
- LRRC37A2 | c.168G>A p.P56= | Silent (SNP) | VAF 69/287 reads (24%) | catalogued as rs759756743, COSV100238904; called by muse, mutect2, varscan2
- MAP10 | c.1461C>A p.P487= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV101406573; called by muse, mutect2, varscan2
- MDH1B | c.600G>A p.K200= | Silent (SNP) | VAF 40/111 reads (36%) | catalogued as rs757181949, COSV100982381; called by muse, mutect2, varscan2
- MTR | c.3696G>A p.K1232= | Silent (SNP) | VAF 57/176 reads (32%) | catalogued as COSV100855595; called by muse, mutect2, varscan2
- MYLK2 | c.1170C>T p.I390= | Silent (SNP) | VAF 50/87 reads (57%) | catalogued as COSV65658468; called by muse, mutect2, varscan2
- NGF | c.63C>T p.H21= | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as rs1283082525, COSV101049703; called by muse, mutect2, varscan2
- NKX2-2 | c.648C>T p.H216= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as rs751150502, COSV101010637; called by muse, mutect2, varscan2
- NPEPL1 | c.249G>A p.V83= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs769979427, COSV100622609; called by muse, mutect2
- OR5D13 | c.261G>A p.L87= | Silent (SNP) | VAF 84/228 reads (37%) | catalogued as COSV62332855; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.993C>T p.D331= (on ENST00000374531 / NM_001037293.2; = p.D363= on NM_053016.6) | Silent (SNP) | VAF 57/157 reads (36%) | catalogued as rs776106715, COSV57111631; called by muse, mutect2, varscan2
- PDLIM7 | c.1152C>T p.G384= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs371472586; called by muse, mutect2, varscan2
- PHF21B | c.501C>T p.T167= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs765319355, COSV57556402; called by muse, mutect2, varscan2
- PPP1R16A | c.6C>T p.A2= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs199970872; called by muse, varscan2
- RAD51C | c.262C>T p.L88= | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as rs786201383, COSV99543842; ClinVar: likely benign; called by muse, mutect2, varscan2
- RD3 | c.510C>T p.S170= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV65363011; called by muse, mutect2, varscan2
- RIMS2 | c.1806C>A p.G602= (on ENST00000666250 / NM_001348490.2; = p.G410= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 65/133 reads (49%) | catalogued as COSV99203261; called by muse, mutect2, varscan2
- SETD2 | c.7077G>T p.G2359= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as COSV100340173; called by muse, mutect2, varscan2
- SLC32A1 | c.333C>T p.H111= | Silent (SNP) | VAF 48/136 reads (35%) | catalogued as rs745654558, COSV99462734; called by muse, mutect2, varscan2
- SPATA21 | c.345G>A p.R115= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as COSV100131420; called by muse, mutect2
- TMEM39B | c.810C>T p.L270= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as COSV100298283; called by muse, mutect2, varscan2
- TRPM3 | c.897C>T p.N299= (on ENST00000357533 / NM_001366142.2; = p.N144= on NM_020952.6) | Silent (SNP) | VAF 55/177 reads (31%) | catalogued as rs201646902, COSV62467895, COSV62468247; called by muse, mutect2, varscan2
- UBQLNL | c.150C>T p.I50= | Silent (SNP) | VAF 54/76 reads (71%) | catalogued as COSV100975756, COSV66493326; called by muse, mutect2, varscan2
- ZNF492 | c.1107A>G p.V369= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs1159349822, COSV101514073; called by mutect2, varscan2
- ZNF92 | c.249A>G p.Q83= (on ENST00000328747 / NM_152626.4; = p.Q14= on NM_007139.4) | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV100166018; called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57621752 G>A | 3'Flank (SNP) | VAF 12/32 reads (38%) | catalogued as rs761902183, COSV54090635; called by muse, mutect2, varscan2
- CCN6 | c.590-1183C>T | Intron (SNP) | VAF 37/70 reads (53%) | catalogued as COSV100037233; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055757 C>T | 3'Flank (SNP) | VAF 18/101 reads (18%) | catalogued as rs751576128; called by muse, mutect2, varscan2
